Somatic mutation profile of tumor specimen TCGA-GN-A4U9-06A (aliquot TCGA-GN-A4U9-06A-11D-A32N-08) from TCGA case TCGA-GN-A4U9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.7 years (26,178 days).
Specimen TCGA-GN-A4U9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74d297eb-fb64-4af1-bee4-a5f91625a4e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A4U9-10B (Blood Derived Normal), aliquot TCGA-GN-A4U9-10B-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ad9022a-eab7-49a5-a23a-abab937ee3b7

The open-access MAF lists 71 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 16, Nonsense Mutation 3, Frame Shift Ins 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 121/192 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACKR1 | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773154872, COSV100929453; called by muse, mutect2, varscan2
- ADGRB3 | c.970A>T p.T324S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV100999603; called by muse, mutect2, varscan2
- C10orf71 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.208); catalogued as rs775875033, COSV60505914, COSV60515402; called by muse, mutect2, varscan2
- CEP97 | c.1331A>G p.E444G | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100511506; called by muse, mutect2, varscan2
- CLCN6 | c.2161T>C p.Y721H | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.11); catalogued as COSV100411510; called by muse, mutect2, varscan2
- CPE | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101291536, COSV68579698; called by muse, mutect2, varscan2
- CUL9 | c.5821C>T p.R1941W | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771775402, COSV52729617; called by muse, mutect2, varscan2
- DDIT3 | c.190A>C p.T64P | Missense Mutation (SNP) | VAF 59/88 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.193); catalogued as COSV100007042; called by muse, mutect2, varscan2
- DNAH2 | c.9325G>A p.D3109N | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101208954; called by muse, mutect2, varscan2
- DNAH5 | c.3776C>T p.A1259V | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as rs532394572, COSV54247933; called by muse, mutect2, varscan2
- EID3 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as COSV100723251; called by muse, mutect2, varscan2
- FAM166A | c.882C>A p.Y294* | Nonsense Mutation (SNP) | VAF 17/157 reads (11%) | catalogued as COSV100457624; called by muse, mutect2, varscan2
- FAM227B | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100174338; called by muse, mutect2, varscan2
- FBXL5 | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100377613; called by muse, mutect2, varscan2
- FBXW7 | c.924T>A p.C308* (on ENST00000281708 / NM_001349798.2; = p.C228* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99653960; called by muse, mutect2, varscan2
- FUT1 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.21); catalogued as rs753532548, COSV99711344; called by muse, mutect2, varscan2
- GABRA1 | c.556A>C p.S186R | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50108312, COSV99195806; called by muse, mutect2, varscan2
- GPX5 | c.373G>T p.G125W | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297235; called by muse, mutect2, varscan2
- GRIA2 | c.296C>G p.T99S | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99642745; called by muse, mutect2, varscan2
- IQGAP1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99184850; called by muse, mutect2, varscan2
- ITGA8 | c.532T>A p.F178I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV100958723, COSV65229081; called by muse, mutect2, varscan2
- ITPR3 | c.1285T>G p.F429V | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100966850; called by muse, mutect2, varscan2
- KNDC1 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100463145; called by muse, mutect2, varscan2
- MACROD2 | c.862G>A p.E288K (on ENST00000642719; = p.E260K on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV54072569; called by muse, mutect2, varscan2
- MINDY2 | c.482G>C p.C161S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV100376232; called by muse, mutect2, varscan2
- MPIG6B | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV101008017; called by mutect2, varscan2
- MYO18A | c.3392A>G p.H1131R | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.977); catalogued as rs1222765186, COSV100571869; called by muse, mutect2, varscan2
- NWD1 | c.3679G>A p.V1227I | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs768341227, COSV100341646; called by muse, mutect2, varscan2
- OCA2 | c.847A>G p.S283G | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100666879; called by muse, mutect2, varscan2
- OGDHL | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750617101, COSV100934181; called by muse, mutect2, varscan2
- PCDHB7 | c.2240A>G p.Y747C | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99175405; called by muse, mutect2, varscan2
- POLR2J | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 31/339 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99484430; called by muse, mutect2
- RAD51AP2 | c.754A>G p.R252G | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.51); catalogued as COSV101208272; called by muse, mutect2, varscan2
- RASGEF1C | c.968C>G p.A323G | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as COSV100745470; called by muse, mutect2, varscan2
- REPS1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV99238346; called by muse, mutect2, varscan2
- RYR1 | c.10510T>G p.S3504A | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as COSV100614230; called by muse, mutect2, varscan2
- SF3A3 | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 115/196 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1317531296, COSV100885586; called by muse, mutect2, varscan2
- SIGLEC5 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as rs765090595, COSV55778632; called by muse, mutect2, varscan2
- SLC24A1 | c.3163G>T p.V1055L | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV56050546, COSV99977998; called by muse, mutect2, varscan2
- SLC25A13 | c.1253A>C p.K418T | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1421663575, COSV99672952; called by muse, mutect2, varscan2
- SLCO1B1 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as COSV99917904; called by muse, mutect2, varscan2
- SLIT3 | c.2120A>T p.Q707L | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.445); catalogued as COSV100265123; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | PolyPhen probably damaging (0.989); catalogued as COSV56570892, COSV99833263; called by muse, mutect2, varscan2
- STT3A | c.259A>T p.T87S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101205103; called by muse, mutect2, varscan2
- TBX19 | c.1196C>A p.A399E | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100892319; called by muse, mutect2, varscan2
- TBX3 | c.353A>G p.K118R | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99983302; called by muse, mutect2, varscan2
- THOC5 | c.816T>G p.F272L | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as COSV100803411; called by muse, mutect2, varscan2
- TMEM53 | c.223G>C p.V75L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.528); catalogued as COSV100698260; called by muse, mutect2, varscan2
- TOM1L1 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100173967; called by muse, mutect2, varscan2
- VWA5A | c.1786A>C p.N596H | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100827686; called by muse, mutect2, varscan2
- HEATR5A | c.4316C>G p.S1439* | Nonsense Mutation (SNP) | VAF 14/195 reads (7%) | called by muse, mutect2
- KIR3DL3 | c.657T>C p.G219= | Splice Region (SNP) | VAF 72/267 reads (27%) | called by muse, mutect2, varscan2
- PCNX2 | c.3416dup p.T1140Nfs*52 | Frame Shift Ins (INS) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- ADNP | c.351C>T p.D117= | Silent (SNP) | VAF 18/306 reads (6%) | catalogued as COSV62425790; called by muse, mutect2
- B4GALT2 | c.381C>T p.G127= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as rs774572710, COSV99356222; called by muse, mutect2, varscan2
- ESPNL | c.2844C>T p.L948= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs746188069, COSV58032550; called by muse, mutect2, varscan2
- GRSF1 | c.1386C>T p.S462= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as rs1449441244, COSV99635471; called by muse, mutect2
- MTMR11 | c.330C>T p.S110= (on ENST00000439741 / NM_001145862.2; = p.S38= on NM_181873.3) | Silent (SNP) | VAF 31/211 reads (15%) | catalogued as rs372576239; called by muse, mutect2, varscan2
- NPAP1 | c.1977T>G p.A659= | Silent (SNP) | VAF 79/136 reads (58%) | catalogued as COSV100274672, COSV100274894; called by muse, mutect2, varscan2
- NUMA1 | c.4110G>A p.L1370= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1233518075, COSV100705727; called by mutect2, varscan2
- OR2T27 | c.546T>C p.P182= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100788096; called by mutect2, varscan2
- PLEKHA4 | c.2280C>T p.V760= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV99611995; called by muse, mutect2, varscan2
- PLVAP | c.396C>T p.Y132= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as COSV99391466; called by muse, mutect2
- RAP1GAP | c.363C>T p.I121= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs373093872, COSV99265988; called by muse, mutect2, varscan2
- SRC | c.966T>C p.H322= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV100657961; called by muse, mutect2, varscan2
- TBL3 | c.2211G>T p.V737= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as COSV100224656; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2247T>G p.A749= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV99648153; called by muse, mutect2, varscan2
- ZDHHC14 | c.1266G>A p.T422= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs756353858, COSV100399002; called by muse, mutect2
- ZNF420 | c.1845T>C p.Y615= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100421106; called by muse, mutect2, varscan2
- DDX41 | c.*556G>A | 3'UTR (SNP) | VAF 59/290 reads (20%) | catalogued as COSV57252178, COSV57253026; called by muse, mutect2, varscan2
